Surgical pathology report (de-identified scan), TCGA case TCGA-YT-A95H, project TCGA-THYM (Thymoma), tissue source site Barretos Cancer Hospital, specimen TCGA-YT-A95H-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Mediastinum

"Mediastinum tumor"

Type AB Thymoma (measures 6.0 x 5.5cm)

ICD O-3
Thymoma, type AB NOS
8582/1
Site: Anterior mediastinum
path
Mediastinum NOS
C38.1
C38.3
7/25/13/14

IHPAA Discrepancy		☒
Other Malignancy History		☒

Source: NCI Genomic Data Commons file cf1bc78c-ddc0-4000-b12b-a78fd94e757f (TCGA-YT-A95H.F394C6F3-0242-45D5-B5CD-8B74010A5A6B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).